Somatic mutation profile of tumor specimen TCGA-BR-4366-01A (aliquot TCGA-BR-4366-01A-01D-1158-08) from TCGA case TCGA-BR-4366, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G2; Age at diagnosis: 87.7 years (32,024 days).
Specimen TCGA-BR-4366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d26bd642-1aa5-487b-a9dc-d0975ece4bc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4366-11A (Solid Tissue Normal), aliquot TCGA-BR-4366-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3467d97d-8979-448c-96c0-d9ed13c06387

The open-access MAF lists 150 somatic variants for this specimen: 111 protein-altering or splice-affecting, 36 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 36, Nonsense Mutation 7, Splice Site 4, Frame Shift Ins 2, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as rs1057519883, CM091776, COSV58698367, COSV58724838, COSV58729341; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 93/117 reads (79%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSS3 | c.1615G>C p.D539H | Missense Mutation (SNP) | VAF 72/233 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54097335; called by muse, varscan2
- ACTR1A | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482600222, COSV64023933; called by muse, mutect2, varscan2
- ADAM8 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs370951632; called by muse, mutect2, varscan2
- ADPGK | c.547C>G p.P183A | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61174716; called by muse, mutect2, varscan2
- ALDH1L2 | c.2035A>C p.I679L | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV51558306; called by muse, mutect2, varscan2
- ALPP | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV67397307; called by mutect2, varscan2
- ARHGAP15 | c.799A>C p.T267P | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV54511397; called by muse, mutect2, varscan2
- ARID1B | c.5031C>A p.C1677* | Nonsense Mutation (SNP) | VAF 329/954 reads (34%) | catalogued as rs1457736861, COSV51673445; called by muse, varscan2
- ARMC3 | c.2267G>A p.G756D | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53065163; called by muse, mutect2, varscan2
- ATP1B3 | c.718A>G p.N240D | Missense Mutation (SNP) | VAF 146/356 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs750790206, COSV53951037; called by muse, mutect2, varscan2
- CAMTA1 | c.2558C>T p.S853L | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs761945718, COSV57917125; called by muse, mutect2, varscan2
- CARS2 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs146878400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH8 | c.1641C>G p.I547M | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV54886345; called by muse, mutect2, varscan2
- CHRM2 | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV57770184, COSV57778914; called by muse, mutect2, varscan2
- CLN6 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.408); catalogued as rs781313960, COSV51117529; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNTN6 | c.1365-1G>C p.X455_splice | Splice Site (SNP) | VAF 37/73 reads (51%) | catalogued as COSV100610010, COSV63182469; called by muse, mutect2, varscan2
- CNTN6 | c.2322T>G p.F774L | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV63182478; called by muse, mutect2, varscan2
- CNTNAP2 | c.2820G>C p.L940F | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV62228033; called by muse, mutect2, varscan2
- COL1A2 | c.4028A>C p.D1343A | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51962824; called by muse, mutect2
- COL1A2 | c.4030A>T p.I1344F | Missense Mutation (SNP) | VAF 158/359 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV51962839; called by muse, mutect2
- COL6A6 | c.6464G>A p.G2155D | Missense Mutation (SNP) | VAF 143/382 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs1287521324, COSV62032436; called by muse, mutect2, varscan2
- CPAMD8 | c.1702C>T p.R568C (on ENST00000651564; = p.R521C on NM_015692.5) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs762584662, COSV52230795; called by muse, mutect2, varscan2
- CSPP1 | c.2973G>C p.M991I (on ENST00000676605; = p.M950I on NM_024790.6) | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV51589494, COSV99139592; called by mutect2, varscan2
- CXCL8 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56641241; called by muse, mutect2, varscan2
- DCUN1D3 | c.431+2T>G p.X144_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as COSV60954319; called by muse, mutect2, varscan2
- DEFB136 | c.101C>G p.T34S | Missense Mutation (SNP) | VAF 75/432 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.641); catalogued as COSV66363998; called by muse, mutect2, varscan2
- DNAI4 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 80/202 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs1325809727, COSV64022924; called by muse, mutect2, varscan2
- DONSON | c.632G>C p.R211P | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51678784; called by muse, mutect2, varscan2
- DPYD | c.1146A>T p.E382D | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1468694722, COSV64608681; called by muse, mutect2, varscan2
- DZIP3 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV64313130; called by muse, mutect2, varscan2
- EFCAB6 | c.4274T>A p.L1425Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53068635; called by muse, mutect2
- ELFN2 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs747077460, COSV68745648; called by muse, mutect2, varscan2
- ENTPD7 | c.172C>G p.R58G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs370286436, COSV65112839, COSV65113100; called by muse, mutect2, varscan2
- EPHX3 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55655868; called by muse, mutect2, varscan2
- FAM135B | c.1933A>C p.S645R | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.235); catalogued as rs756192058, COSV52714592; called by muse, mutect2, varscan2
- FER1L5 | c.4081C>T p.L1361F (on ENST00000623019; = p.L1334F on NM_001293083.2) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67606662; called by muse, mutect2, varscan2
- FGF10 | c.14T>G p.I5R | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52937627; called by muse, mutect2, varscan2
- FMO2 | c.1159C>A p.R387S | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV52947425, COSV99269351; called by muse, mutect2, varscan2
- FMO5 | c.1388T>C p.L463S | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV54209260; called by muse, mutect2, varscan2
- FRMPD4 | c.3107G>C p.G1036A | Missense Mutation (SNP) | VAF 81/109 reads (74%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV66220229; called by muse, mutect2, varscan2
- FYB2 | c.68C>G p.P23R | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); catalogued as COSV58587518; called by muse, mutect2
- G2E3 | c.2004C>G p.N668K | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV52842000; called by muse, mutect2, varscan2
- GLDC | c.610G>T p.A204S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs757620314, COSV58678697, COSV58683145; called by muse, mutect2, varscan2
- GTF3C3 | c.1790C>G p.S597* | Nonsense Mutation (SNP) | VAF 41/92 reads (45%) | catalogued as COSV55833629; called by muse, mutect2, varscan2
- HTR1F | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60390770; called by muse, mutect2, varscan2
- IGLV3-32 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs765256614; called by muse, mutect2, varscan2
- IKZF1 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.589); catalogued as rs750934235, COSV58781201; called by muse, mutect2, varscan2
- ITGB5 | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56151545; called by muse, mutect2, varscan2
- KATNA1 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV59503526; called by muse, mutect2, varscan2
- KIAA0408 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 43/270 reads (16%) | catalogued as COSV100847076, COSV64105196; called by muse, mutect2, varscan2
- KRT33A | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs536221397, COSV50370912, COSV99144957; called by muse, mutect2, varscan2
- LRP1B | c.8269+1G>A p.X2757_splice | Splice Site (SNP) | VAF 61/188 reads (32%) | catalogued as COSV67253771; called by muse, mutect2, varscan2
- LRP1B | c.4402T>A p.Y1468N | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV67253774; called by muse, mutect2, varscan2
- LRRK2 | c.1514T>G p.L505R | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54163263; called by muse, mutect2
- MAOA | c.1556A>T p.Y519F | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV58644523; called by muse, mutect2
- MARK1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 147/179 reads (82%) | catalogued as rs1346347772, COSV65068250; called by muse, mutect2, varscan2
- MATN4 | c.1439C>T p.A480V (on ENST00000372754; = p.A439V on NM_003833.4) | Missense Mutation (SNP) | VAF 44/238 reads (18%) | PolyPhen benign (0.056); catalogued as rs532253887, COSV61352250; called by muse, mutect2, varscan2
- METTL24 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1400839022, COSV58823229; called by muse, mutect2, varscan2
- MRPS35 | c.188A>G p.D63G | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV50012012; called by muse, mutect2, varscan2
- MUC16 | c.39481A>G p.T13161A | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV66695014; called by muse, mutect2, varscan2
- NAA11 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54515344; called by muse, mutect2
- NCOR2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs776360455, COSV62301493; called by muse, mutect2, varscan2
- NFATC2 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs376937921; called by muse, mutect2, varscan2
- NHS | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV66279510; called by muse, mutect2, varscan2
- OCA2 | c.1413A>C p.E471D | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV62353121; called by muse, mutect2, varscan2
- OLFML2B | c.1415C>A p.T472K | Missense Mutation (SNP) | VAF 150/611 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.019); catalogued as COSV54198881; called by muse, mutect2, varscan2
- OR10J5 | c.112A>C p.T38P | Missense Mutation (SNP) | VAF 64/469 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV58387105; called by muse, mutect2, varscan2
- OR2G6 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV58574424, COSV58576188; called by muse, mutect2, varscan2
- OVGP1 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1250153179, COSV63859378; called by muse, mutect2, varscan2
- P2RY8 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs761542234, COSV67176754; called by muse, mutect2, varscan2
- P4HTM | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1316631077, COSV59088418; called by muse, mutect2, varscan2
- PABPC5 | c.114C>A p.F38L | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV57042254; called by muse, mutect2, varscan2
- PABPC5 | c.115A>G p.R39G | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV57042267; called by muse, mutect2, varscan2
- PAQR3 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 69/103 reads (67%) | catalogued as rs1209233230, COSV55011057; called by muse, mutect2, varscan2
- PCDHGB7 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as COSV53998269; called by muse, mutect2, varscan2
- PEX3 | c.427G>T p.D143Y | Missense Mutation (SNP) | VAF 86/247 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62569238; called by muse, mutect2, varscan2
- PHF20 | c.1601A>G p.K534R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV59187762; called by muse, mutect2
- PLAAT5 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as COSV57137914; called by muse, mutect2, varscan2
- PLEKHA1 | c.216G>C p.K72N | Missense Mutation (SNP) | VAF 216/362 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64569947; called by muse, mutect2, varscan2
- POGLUT2 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV65683432; called by muse, mutect2, varscan2
- QSER1 | c.4058A>G p.Q1353R (on ENST00000399302; = p.Q1482R on NM_001076786.3) | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV67901318; called by muse, mutect2, varscan2
- RAE1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 203/648 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.769); catalogued as rs1384868563, COSV64798620; called by muse, mutect2, varscan2
- RAPGEFL1 | c.1127T>C p.L376P | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52864350; called by muse, mutect2, varscan2
- RECQL4 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376045624; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- ROCK1 | c.3484T>C p.S1162P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV67697851; called by muse, mutect2
- SCARA3 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 76/258 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.657); catalogued as rs1239301709, COSV57271138; called by muse, mutect2, varscan2
- SEMA4D | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756135411, COSV59398696; called by muse, mutect2, varscan2
- SH3RF3 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs530586447, COSV58685492; called by muse, mutect2, varscan2
- SLC19A2 | c.481T>G p.C161G | Missense Mutation (SNP) | VAF 30/327 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV52548409; called by muse, mutect2
- SLC1A6 | c.1141C>A p.L381I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV55672459; called by muse, mutect2, varscan2
- SLC25A38 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs143865753, COSV56194714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC36A2 | c.334T>C p.F112L | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1203207538, COSV58864370; called by muse, mutect2
- SPTA1 | c.6710G>C p.G2237A | Missense Mutation (SNP) | VAF 80/731 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63752722, COSV63757175; called by muse, mutect2, varscan2
- SPTBN4 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs1049492195, COSV58945661; called by muse, mutect2, varscan2
- STAG1 | c.56A>G p.H19R | Missense Mutation (SNP) | VAF 119/305 reads (39%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.599); catalogued as COSV52609521, COSV52618387; called by muse, mutect2, varscan2
- STAU2 | c.895G>A p.G299R (on ENST00000524300 / NM_001164380.2; = p.G267R on NM_014393.2) | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); catalogued as rs142831475; called by muse, mutect2, varscan2
- TNIP1 | c.1009G>T p.E337* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV59309000; called by muse, mutect2, varscan2
- TOX4 | c.1402C>G p.P468A | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52968782; called by muse, mutect2, varscan2
- UST | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs773744901, COSV66549114; called by muse, mutect2, varscan2
- VPS50 | c.1453-2A>G p.X485_splice | Splice Site (SNP) | VAF 47/127 reads (37%) | catalogued as COSV58509819; called by muse, mutect2, varscan2
- ZEB2 | c.3466G>T p.G1156C | Missense Mutation (SNP) | VAF 128/414 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as rs776351453, COSV57962253; called by muse, mutect2, varscan2
- ZFP69B | c.1059T>A p.H353Q | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64315890; called by muse, mutect2, varscan2
- ZNF10 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50213740; called by muse, mutect2, varscan2
- ZNF536 | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 64/792 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV62830193; called by muse, mutect2
- ZNF800 | c.1286A>C p.N429T | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.045); catalogued as COSV56178531; called by muse, mutect2
- PRAMEF17 | c.278T>G p.L93R | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- PRKG2 | c.1197dup p.Y400Ifs*3 | Frame Shift Ins (INS) | VAF 38/177 reads (21%) | called by mutect2, pindel, varscan2
- VEZT | c.597dup p.Y200Ifs*17 | Frame Shift Ins (INS) | VAF 92/280 reads (33%) | called by mutect2, varscan2
- ADGRL2 | c.252C>T p.C84= | Silent (SNP) | VAF 71/227 reads (31%) | catalogued as COSV54679732; called by muse, mutect2, varscan2
- AK3 | c.81C>T p.I27= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs751069757, COSV63346957; called by muse, mutect2, varscan2
- ASXL3 | c.2028G>A p.L676= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as COSV52474005; called by muse, mutect2
- ATP6V1B2 | c.357C>T p.L119= | Silent (SNP) | VAF 129/273 reads (47%) | catalogued as rs1204602479, COSV52354301, COSV52354589; called by muse, mutect2, varscan2
- CAPRIN1 | c.1137T>C p.D379= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as COSV58221414; called by muse, mutect2, varscan2
- CCDC105 | c.243C>T p.G81= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99480136; called by muse, mutect2
- CDH8 | c.315T>G p.A105= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs761336806, COSV54886359; called by muse, mutect2, varscan2
- DNAH7 | c.11406G>A p.S3802= | Silent (SNP) | VAF 100/304 reads (33%) | catalogued as rs765905199, COSV56776875; called by muse, mutect2, varscan2
- DST | c.9147T>A p.I3049= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV99759880, COSV99760125; called by muse, mutect2, varscan2
- EBF1 | c.949C>A p.R317= | Silent (SNP) | VAF 73/217 reads (34%) | catalogued as COSV58188568; called by muse, mutect2, varscan2
- ELAVL3 | c.894C>T p.S298= | Silent (SNP) | VAF 61/135 reads (45%) | catalogued as rs768770817, COSV52952913; called by muse, mutect2, varscan2
- FANCB | c.399C>T p.G133= | Silent (SNP) | VAF 51/62 reads (82%) | catalogued as COSV60761107; called by muse, mutect2, varscan2
- FLCN | c.546C>A p.L182= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV53261649; called by muse, mutect2, varscan2
- FMO1 | c.1096C>T p.L366= | Silent (SNP) | VAF 60/340 reads (18%) | catalogued as COSV61447072; called by muse, varscan2
- HMCN1 | c.3300A>G p.P1100= | Silent (SNP) | VAF 60/388 reads (15%) | catalogued as rs750155072, COSV54924172; called by muse, mutect2, varscan2
- KCNJ4 | c.744C>T p.I248= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs752839382, COSV57858066; called by muse, mutect2, varscan2
- LAMA5 | c.9588C>T p.F3196= | Silent (SNP) | VAF 68/257 reads (26%) | catalogued as rs746763126, COSV53359697, COSV53366971; called by muse, mutect2, varscan2
- NOL6 | c.2193C>T p.Y731= | Silent (SNP) | VAF 79/191 reads (41%) | catalogued as rs759064707, COSV53044524; called by muse, mutect2, varscan2
- OR8B12 | c.93G>T p.L31= | Silent (SNP) | VAF 50/149 reads (34%) | catalogued as COSV60912361; called by muse, mutect2, varscan2
- PCDHA3 | c.201G>A p.A67= | Silent (SNP) | VAF 129/369 reads (35%) | catalogued as COSV65369622; called by muse, mutect2, varscan2
- PCDHGA10 | c.1977C>T p.S659= | Silent (SNP) | VAF 52/147 reads (35%) | catalogued as COSV53986372; called by muse, mutect2, varscan2
- PGR | c.2556C>G p.L852= | Silent (SNP) | VAF 32/103 reads (31%) | catalogued as COSV54807296; called by muse, mutect2, varscan2
- POTEF | c.2448C>T p.R816= | Silent (SNP) | VAF 134/360 reads (37%) | catalogued as rs562326654, COSV100665255, COSV62545450; called by muse, varscan2
- PRPSAP1 | c.384C>T p.F128= | Silent (SNP) | VAF 100/281 reads (36%) | catalogued as rs773571508, COSV61212195; called by muse, mutect2, varscan2
- RXFP3 | c.1110G>A p.A370= | Silent (SNP) | VAF 74/376 reads (20%) | catalogued as COSV57505551; called by muse, mutect2, varscan2
- SHC2 | c.1617C>T p.G539= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs368330262; called by muse, varscan2
- SQSTM1 | c.1317G>A p.P439= | Silent (SNP) | VAF 104/278 reads (37%) | catalogued as rs11548636, COSV52972947; called by muse, mutect2, varscan2
- TAX1BP1 | c.1272T>C p.T424= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV55295504; called by muse, mutect2, varscan2
- TG | c.8199G>A p.K2733= | Silent (SNP) | VAF 86/139 reads (62%) | catalogued as COSV55088062; called by muse, mutect2, varscan2
- TMEM115 | c.441G>C p.V147= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV51705259; called by muse, mutect2, varscan2
- TMTC1 | c.2056T>C p.L686= (on ENST00000539277 / NM_001193451.2; = p.L578= on NM_175861.3) | Silent (SNP) | VAF 125/272 reads (46%) | catalogued as rs1418923533, COSV55488782; called by muse, mutect2, varscan2
- TMUB1 | c.24T>C p.G8= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV52541426; called by muse, mutect2, varscan2
- ULK2 | c.2397C>T p.P799= | Silent (SNP) | VAF 184/258 reads (71%) | catalogued as COSV64447346; called by muse, mutect2, varscan2
- ZC3H6 | c.2211C>G p.L737= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV59669635; called by muse, mutect2, varscan2
- ZNF217 | c.2029A>C p.R677= | Silent (SNP) | VAF 1700/2241 reads (76%) | catalogued as COSV56600418; called by muse, mutect2, varscan2
- ZNF257 | c.1473A>G p.E491= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV71310512; called by muse, varscan2
- DCAF13 | chr8:103415344 T>G | 5'Flank (SNP) | VAF 20/172 reads (12%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- TTI2 | chr8:33513532 G>A | 5'Flank (SNP) | VAF 83/252 reads (33%) | catalogued as rs558826711, COSV100659822; called by muse, mutect2, varscan2
- ZNF658B | n.776T>G | RNA (SNP) | VAF 117/258 reads (45%) | called by muse, mutect2, varscan2
